Somatic mutation profile of tumor specimen PCProject_0182_T1_WES (aliquot PCProject_0182_T1_WES_1) from CMI case PCProject_0182, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.4 years (21,326 days).
Specimen PCProject_0182_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3e1d8e7-6b0f-4520-bbcf-38ec8ea9db8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0182_SALIVA (Saliva), aliquot PCProject_0182_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4185adf7-ea56-49bb-b766-99d0b7128a9f

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 2, RNA 2, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.579); catalogued as rs200327053, COSV53444530; called by muse, mutect2, varscan2
- ADAM12 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs369702251; called by muse, mutect2, varscan2
- ALG14 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64634601; called by muse, mutect2, varscan2
- BMPER | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145067547; called by muse, mutect2, varscan2
- EFCAB1 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs751867551; called by muse, mutect2, varscan2
- GPSM3 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs771764802; called by muse, mutect2, varscan2
- SLC6A3 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs745426965, COSV99548502; called by muse, mutect2, varscan2
- SSC5D | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1206866487; called by muse, mutect2, varscan2
- TMCO6 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs370199625; called by muse, mutect2, varscan2
- TRPC3 | c.997C>T p.R333W (on ENST00000379645 / NM_001366479.2; = p.R260W on NM_003305.2) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs200628425, COSV53381860; called by muse, mutect2
- ZNF584 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1438488382, COSV59721981; called by muse, mutect2, varscan2
- CAPZA3 | c.532G>T p.V178F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- CARM1 | c.1600A>C p.N534H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CDC42BPB | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- IFT172 | c.5245_5247del p.Q1749del | In Frame Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- JPH3 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2
- NLRP2 | c.2536T>C p.S846P | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- SERAC1 | c.285A>C p.R95S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- SUMF2 | c.958G>T p.A320S (on ENST00000652303; = p.A301S on NM_001130069.4) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TP53 | c.445_446insGT p.S149Cfs*22 | Frame Shift Ins (INS) | VAF 22/49 reads (45%) | called by mutect2, pindel, varscan2
- ZNF208 | c.3023A>G p.K1008R | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF700 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 53/171 reads (31%) | called by muse, mutect2, varscan2
- ABR | c.87C>T p.Y29= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs760840220, COSV56831941; called by muse, mutect2, varscan2
- BCAN | c.1819C>T p.L607= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- CDH4 | c.546G>A p.S182= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1003829832, COSV64659909; called by muse, mutect2, varscan2
- DNAH10 | c.8571C>T p.R2857= (on ENST00000409039; = p.R2796= on NM_207437.3) | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs984555280, COSV68991099; called by muse, mutect2, varscan2
- DNAH3 | c.396G>A p.P132= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs1247781432, COSV54543699, COSV99771189; called by muse, mutect2, varscan2
- ZNF787 | c.282C>T p.N94= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs764130184, COSV54419643; called by muse, mutect2, varscan2
- CYP2B7P | n.505C>T | RNA (SNP) | VAF 13/122 reads (11%) | catalogued as rs779155468; called by muse, mutect2, varscan2
- GLOD4 | chr17:782585 G>A | 5'Flank (SNP) | VAF 29/50 reads (58%) | catalogued as COSV56752582; called by muse, mutect2, varscan2
- RPL23AP87 | n.1468C>T | RNA (SNP) | VAF 43/223 reads (19%) | called by muse, mutect2, varscan2
